Somatic mutation profile of tumor specimen TCGA-DJ-A2Q2-01A (aliquot TCGA-DJ-A2Q2-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2Q2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 57.4 years (20,951 days).
Specimen TCGA-DJ-A2Q2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c260a66-9991-4a0a-9d35-c267bc6f1551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q2-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q2-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/884bcbd2-cd36-48ed-a84e-57d97186aa5f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A1 | c.995T>G p.V332G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724160010, COSV55190106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNTNAP1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 20/160 reads (13%) | catalogued as COSV52848410; called by muse, mutect2, varscan2
- COL4A6 | c.3122C>G p.P1041R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57860615; called by muse, mutect2, varscan2
- CTNND2 | c.2637G>A p.K879= | Splice Region (SNP) | VAF 4/74 reads (5%) | catalogued as COSV58871304; called by muse, mutect2
- RASGRF2 | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772936233, COSV54124556; called by muse, mutect2, varscan2
- C1QL2 | c.654C>T p.S218= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV55606145; called by muse, mutect2, varscan2
- KTN1 | c.3747A>G p.V1249= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58539982; called by muse, mutect2, varscan2
